MMRF case MMRF_2592 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/313c09b1-85b4-41eb-923d-a3756e6e6b2f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.8 years (21,839 days); ISS stage: III; Days to last known disease status: 594 days (1.6 years); Days to last follow up: 594 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 125 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 168 days; Days to treatment end: 168 days.
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 282 days; Days to treatment end: 394 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 415 days (1.1 years); Days to treatment end: 468 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 482 days (1.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 371 mg/dL; Immunoglobulin G 1.02 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 13.9 µg/mL; Lactate Dehydrogenase 4.47 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 339 µmol/L; Blood Urea Nitrogen 17.9 mmol/L; Calcium 3.1 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 5.39 mmol/L.
- Day 97 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 69.5 mg/dL; Immunoglobulin G 6.43 g/L; Immunoglobulin A 0.592 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 7 µg/mL; Lactate Dehydrogenase 3.88 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 8.5 ×10⁹/L; Platelets 268 ×10⁹/L; Creatinine 130 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 8.8 mmol/L.
- Day 187 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.6 mg/dL; Immunoglobulin G 4.22 g/L; Immunoglobulin A 0.378 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 6.38 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 46 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 8.03 mmol/L.
- Day 268 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 5.1 µg/mL; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.01 mmol/L.
- Day 366 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 6.52 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L.
- Day 447 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 7.69 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.89 mmol/L.
- Day 510 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Immunoglobulin G 8.4 g/L; Immunoglobulin A 1.78 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 4.84 mmol/L.
- Day 594 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.4 mg/dL; Immunoglobulin G 9.17 g/L; Immunoglobulin A 2.13 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.7 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.12 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -2: Weight: 74 kg; Height: 152 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Kidney Cancer.

Biospecimens (2 samples)
- Sample MMRF_2592_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_2592_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
